Somatic mutation profile of tumor specimen TCGA-D6-A6EK-01A (aliquot TCGA-D6-A6EK-01A-11D-A31L-08) from TCGA case TCGA-D6-A6EK, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-D6-A6EK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e018f259-ae08-405b-9761-2a5de8b67519.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D6-A6EK-10A (Blood Derived Normal), aliquot TCGA-D6-A6EK-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63830a75-60b3-4eb7-a1f3-808b1b4f8f9e

The open-access MAF lists 179 somatic variants for this specimen: 135 protein-altering or splice-affecting, 41 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 41, Nonsense Mutation 14, Frame Shift Del 7, Frame Shift Ins 3, Intron 2, Splice Region 2, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC5 | c.3901G>A p.D1301N | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV99656603; called by muse, mutect2, varscan2
- ADAMTS19 | c.2819G>A p.G940E | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV50746703; called by muse, mutect2, varscan2
- ADAMTS9 | c.5464G>T p.A1822S | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as COSV99898987; called by muse, mutect2, varscan2
- AKAP1 | c.2465C>A p.A822E | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100532722; called by muse, mutect2, varscan2
- ALX3 | c.463C>A p.R155S | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100873871; called by muse, mutect2, varscan2
- ANKMY1 | c.2441G>T p.R814L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.311); catalogued as COSV99801608; called by muse, mutect2, varscan2
- AQR | c.1974G>C p.R658S | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50039004, COSV99333505; called by muse, mutect2, varscan2
- ARHGAP32 | c.5744C>T p.S1915F (on ENST00000310343 / NM_001378025.1; = p.S1566F on NM_014715.4) | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV100087240; called by muse, mutect2, varscan2
- ARID5B | c.2910A>T p.E970D | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV99689252; called by muse, mutect2, varscan2
- ARMC4 | c.1333G>T p.A445S | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as COSV53465905; called by muse, mutect2
- ASPH | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV65249356; called by muse, mutect2, varscan2
- ATG101 | c.253G>T p.D85Y | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV100400990, COSV61084974; called by muse, mutect2, varscan2
- BICD1 | c.1825T>A p.S609T | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.629); catalogued as COSV99862138; called by muse, mutect2, varscan2
- CASP8 | c.1237C>T p.R413* (on ENST00000432109 / NM_033355.3; = p.R430* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 27/55 reads (49%) | catalogued as rs1272714323, COSV51845663; called by muse, mutect2, varscan2
- CDH4 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100848540, COSV100849420; called by muse, mutect2, varscan2
- CFAP47 | c.5432T>A p.F1811Y | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.697); catalogued as COSV100545071; called by muse, mutect2, varscan2
- CGNL1 | c.3601A>T p.K1201* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99847758; called by muse, mutect2, varscan2
- CHST10 | c.991G>C p.D331H | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.986); catalogued as COSV99958761; called by muse, mutect2, varscan2
- COBL | c.3515C>G p.S1172C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.87); catalogued as COSV99471748; called by muse, mutect2, varscan2
- COL8A1 | c.982G>A p.G328R | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99657354; called by muse, mutect2, varscan2
- CPT1B | c.1279T>C p.S427P | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.217); catalogued as COSV100376546; called by muse, mutect2, varscan2
- CTDSPL2 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0.025); catalogued as COSV99526671; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1739C>T p.P580L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99599858; called by muse, mutect2, varscan2
- DIAPH3 | c.1100G>A p.R367H (on ENST00000400324 / NM_001042517.2; = p.R104H on NM_030932.3) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs770872230, COSV57378679; called by muse, mutect2, varscan2
- DMGDH | c.1325A>G p.E442G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.011); catalogued as COSV99668628; called by muse, mutect2, varscan2
- DNAJB8 | c.110A>T p.D37V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs779641429, COSV100048174; called by muse, mutect2, varscan2
- DNASE2B | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101042062; called by muse, mutect2, varscan2
- DNMT3A | c.2695C>T p.R899C | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs771922296, COSV53056751, COSV53070898; called by muse, mutect2, varscan2
- DOCK5 | c.4366G>A p.A1456T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.034); catalogued as COSV99376402; called by muse, mutect2, varscan2
- DPP4 | c.1867C>T p.R623* | Nonsense Mutation (SNP) | VAF 29/55 reads (53%) | catalogued as rs745777648, COSV62106316; called by muse, mutect2, varscan2
- DPPA2 | c.661G>A p.V221I | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.778); catalogued as rs199811743; called by muse, mutect2, varscan2
- DPYD | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100031689; called by muse, mutect2, varscan2
- EBF3 | c.822G>T p.W274C (on ENST00000355311 / NM_001375392.1; = p.W265C on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV62478329; called by muse, mutect2, varscan2
- EEF2 | c.1696G>A p.A566T | Missense Mutation (SNP) | VAF 26/151 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.709); catalogued as rs749851802, COSV58578690; called by muse, mutect2, varscan2
- EML4 | c.1955C>A p.T652K | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100580751; called by muse, mutect2, varscan2
- EPHA5 | c.310G>T p.V104L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV99897234; called by muse, mutect2, varscan2
- FAR2 | c.1276C>T p.R426C | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs370381799; called by muse, mutect2, varscan2
- FARSA | c.1198A>G p.I400V | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs759410011, COSV100108729; called by muse, mutect2, varscan2
- FAT1 | c.4288G>T p.E1430* | Nonsense Mutation (SNP) | VAF 27/101 reads (27%) | catalogued as COSV101499164; called by muse, mutect2, varscan2
- FAT4 | c.2324A>T p.N775I | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.33); catalogued as COSV101272156; called by muse, mutect2, varscan2
- FLT4 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs1368679940, COSV56105858, COSV56106564; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1110A>T p.Q370H | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV100436016; called by muse, mutect2, varscan2
- FSTL3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.261); catalogued as rs928073841, COSV99383829; called by muse, mutect2, varscan2
- FZD1 | c.1580C>T p.T527I | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as rs1348199807, COSV99842437; called by muse, mutect2, varscan2
- GRM1 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51323579; called by muse, mutect2, varscan2
- GRXCR1 | c.337G>C p.V113L | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV101295635; called by muse, mutect2, varscan2
- HAS3 | c.186T>A p.F62L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99544192; called by muse, mutect2, varscan2
- HCN1 | c.1982G>C p.R661T | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.104); catalogued as COSV100299258; called by muse, mutect2, varscan2
- HDGFL1 | c.37G>A p.D13N | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100014534; called by muse, mutect2, varscan2
- HFM1 | c.1904A>G p.Y635C | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99645619; called by muse, mutect2, varscan2
- HNRNPUL1 | c.2482C>T p.Q828* | Nonsense Mutation (SNP) | VAF 37/132 reads (28%) | catalogued as COSV99523653; called by muse, mutect2, varscan2
- HTR1A | c.1144G>A p.G382S | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.438); catalogued as rs746894232, COSV100108990, COSV60499756, COSV60503319; called by muse, mutect2, varscan2
- HUWE1 | c.8491A>G p.I2831V | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); catalogued as COSV99471160; called by muse, mutect2, varscan2
- IGHV3-74 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs761210990; called by muse, mutect2, varscan2
- IGKV1-16 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1306308414; called by muse, mutect2, varscan2
- IKZF5 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV100924733; called by mutect2, varscan2
- KDM7A | c.2023A>G p.I675V | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1364015873, COSV99134073; called by muse, mutect2, varscan2
- KIF16B | c.2212G>A p.D738N | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs143610596, COSV100733957; called by muse, mutect2, varscan2
- KLC4 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV99431523; called by muse, mutect2, varscan2
- LPCAT3 | c.1415T>A p.I472N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as COSV99781008; called by muse, mutect2, varscan2
- LRFN2 | c.223A>G p.M75V | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100599253; called by muse, mutect2, varscan2
- LRP5 | c.4381G>T p.V1461L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV99591621; called by muse, mutect2, varscan2
- LTA | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 27/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101403155; called by muse, mutect2, varscan2
- MAGI1 | c.984G>T p.W328C | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100439873; called by muse, mutect2, varscan2
- MAP3K19 | c.3688A>G p.T1230A | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100208230; called by muse, mutect2, varscan2
- MCMDC2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV58037681; called by muse, mutect2
- MMP27 | c.859G>A p.A287T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs185328145, COSV52782143; called by muse, mutect2, varscan2
- MORC3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101264881; called by muse, mutect2, varscan2
- MRO | c.448T>C p.Y150H | Missense Mutation (SNP) | VAF 46/226 reads (20%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.967); catalogued as COSV99839066; called by muse, mutect2, varscan2
- MS4A2 | c.309G>T p.W103C | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV99627121; called by muse, mutect2, varscan2
- MSH3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.233); catalogued as rs1362313141, COSV54145156; called by muse, mutect2, varscan2
- MYO19 | c.1949A>G p.H650R (on ENST00000614623 / NM_001163735.1; = p.H450R on NM_025109.5) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.123); catalogued as rs192033792; called by muse, mutect2, varscan2
- NBEAL1 | c.7864A>T p.N2622Y | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV101355424; called by muse, mutect2, varscan2
- NCKAP5 | c.4507G>T p.G1503W | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100490701; called by muse, mutect2, varscan2
- NFE2L2 | c.1684C>T p.L562F | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV101229346; called by muse, mutect2, varscan2
- NPLOC4 | c.1721G>T p.G574V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.021); catalogued as COSV100480727; called by muse, mutect2, varscan2
- NSUN2 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99243034; called by muse, mutect2, varscan2
- OR4D10 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 37/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs780952703, COSV73260172; called by muse, mutect2, varscan2
- OR9G4 | c.633T>G p.I211M | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as COSV100265052; called by muse, mutect2, varscan2
- PAM | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99173166; called by muse, mutect2, varscan2
- PCARE | c.131T>A p.L44Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100527404; called by muse, mutect2, varscan2
- PCDH11Y | c.2818C>T p.P940S (on ENST00000400457 / NM_032973.2; = p.P929S on NM_032971.3) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV99290936; called by muse, mutect2, varscan2
- PCDHGA10 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1299162270, COSV99533640; called by muse, mutect2, varscan2
- PCDHGB7 | c.811G>C p.E271Q | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as COSV53963466, COSV54064780, COSV99533643; called by muse, mutect2, varscan2
- PCLO | c.11891G>T p.R3964L | Missense Mutation (SNP) | VAF 141/432 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369285880, COSV100429081; called by muse, mutect2, varscan2
- PDZD11 | c.387C>T p.Y129= | Splice Region (SNP) | VAF 7/24 reads (29%) | catalogued as COSV99333563; called by muse, mutect2
- PIK3CG | c.683C>T p.T228I | Missense Mutation (SNP) | VAF 58/150 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.033); catalogued as COSV100782675, COSV63246220; called by muse, mutect2, varscan2
- PLCL1 | c.1606A>T p.M536L | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV101406840, COSV70832283; called by muse, mutect2, varscan2
- POM121L12 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.006); catalogued as COSV101374886; called by muse, mutect2, varscan2
- PPEF2 | c.746+1G>A p.X249_splice | Splice Site (SNP) | VAF 30/151 reads (20%) | catalogued as COSV99714284; called by muse, mutect2, varscan2
- PPM1D | c.1741C>T p.R581* | Nonsense Mutation (SNP) | VAF 11/73 reads (15%) | catalogued as rs747668756, COSV59954411; called by muse, mutect2, varscan2
- PRDM16 | c.1961C>T p.A654V | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs771684634, COSV99575913; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKN | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.964); catalogued as rs772592654, COSV100628057, COSV58254631; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PROS1 | c.1358G>T p.W453L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101260332; called by muse, mutect2
- RASD2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99332705; called by muse, mutect2, varscan2
- RASGRF1 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.613); catalogued as rs140019990; called by muse, mutect2, varscan2
- RGPD2 | c.3965G>T p.R1322I | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV100552889; called by mutect2, varscan2
- RIMS2 | c.265G>T p.A89S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.999); catalogued as COSV101344369; called by muse, mutect2, varscan2
- RSF1 | c.2893G>T p.E965* | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100406978; called by muse, mutect2, varscan2
- SETD5 | c.3057T>A p.C1019* | Nonsense Mutation (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100200348; called by muse, mutect2, varscan2
- SGPP2 | c.607G>T p.V203L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1189294889, COSV100346220; called by muse, mutect2, varscan2
- SH2D1A | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.234); catalogued as COSV100758279; called by muse, mutect2, varscan2
- SI | c.4681G>A p.A1561T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.51); PolyPhen benign (0.038); catalogued as rs768264563, COSV100014528; called by muse, mutect2, varscan2
- SLC13A1 | c.1703G>A p.G568D | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99520357; called by muse, varscan2
- SLC5A5 | c.799C>A p.Q267K | Missense Mutation (SNP) | VAF 29/131 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM981846, COSV55832537; called by muse, mutect2, varscan2
- SOX17 | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310101179, COSV99810422; called by muse, mutect2, varscan2
- SPHKAP | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 70/191 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.212); catalogued as COSV100763847; called by muse, mutect2, varscan2
- THNSL2 | c.49G>T p.G17W | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV100147363; called by muse, mutect2, varscan2
- TJP1 | c.1670G>A p.W557* | Nonsense Mutation (SNP) | VAF 11/72 reads (15%) | catalogued as COSV100632479; called by muse, mutect2, varscan2
- TKT | c.1585A>G p.I529V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.77); PolyPhen benign (0.058); catalogued as rs782186345, COSV99964911; called by muse, mutect2, varscan2
- TNS3 | c.1588G>A p.G530S | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV100235121; called by muse, mutect2, varscan2
- TRPC4 | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 23/137 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58990652; called by muse, mutect2, varscan2
- TTN | c.19774G>A p.V6592I (on ENST00000591111; = p.V5665I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | PolyPhen benign (0.003); catalogued as COSV100600641; called by muse, mutect2, varscan2
- TUBGCP3 | c.1846G>A p.E616K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV99996633; called by muse, mutect2, varscan2
- UNC5D | c.2009T>A p.L670Q | Missense Mutation (SNP) | VAF 45/147 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV99773305; called by muse, mutect2, varscan2
- WDR3 | c.67A>G p.K23E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV100832036; called by muse, mutect2, varscan2
- ZBED9 | c.3960A>T p.Q1320H | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101509166; called by muse, mutect2, varscan2
- ZBTB20 | c.1266G>T p.Q422H (on ENST00000474710 / NM_001164342.2; = p.Q349H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.02); catalogued as COSV100613135; called by muse, mutect2, varscan2
- ZFYVE27 | c.884A>T p.H295L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.37); PolyPhen benign (0.261); catalogued as COSV100519222; called by muse, mutect2, varscan2
- ZNF385D | c.620C>A p.S207* | Nonsense Mutation (SNP) | VAF 22/108 reads (20%) | catalogued as COSV55749808, COSV55756553; called by muse, mutect2, varscan2
- ZNF473 | c.2596A>T p.K866* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as COSV99568605; called by muse, mutect2, varscan2
- ZNF518B | c.2116G>C p.G706R | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.168); catalogued as COSV100456614; called by muse, mutect2, varscan2
- ZNF681 | c.373G>T p.G125* | Nonsense Mutation (SNP) | VAF 3/33 reads (9%) | catalogued as COSV101267416; called by muse, mutect2
- ZNF684 | c.493G>T p.G165W | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375475061, COSV101015943; called by muse, mutect2, varscan2
- C1orf216 | c.49dup p.D17Gfs*27 | Frame Shift Ins (INS) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- CYSLTR2 | c.413dup p.A139Gfs*41 | Frame Shift Ins (INS) | VAF 14/119 reads (12%) | called by mutect2, pindel, varscan2
- DNAJB7 | c.468del p.Y157Ifs*63 | Frame Shift Del (DEL) | VAF 12/65 reads (18%) | called by mutect2, pindel, varscan2
- HFM1 | c.1497del p.C500Afs*12 | Frame Shift Del (DEL) | VAF 12/93 reads (13%) | called by mutect2, pindel, varscan2
- NCAPD2 | c.3820del p.A1274Pfs*8 | Frame Shift Del (DEL) | VAF 9/58 reads (16%) | called by mutect2, pindel, varscan2
- NOTCH1 | c.5129del p.G1710Afs*88 | Frame Shift Del (DEL) | VAF 16/50 reads (32%) | called by mutect2, pindel, varscan2
- PCDHGA8 | c.592del p.R198Afs*33 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- RELA | c.1594dup p.E532Gfs*24 | Frame Shift Ins (INS) | VAF 6/55 reads (11%) | called by mutect2, pindel, varscan2
- SLC22A20P | n.1297G>A | Splice Region (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- STOML1 | c.409del p.A137Lfs*20 | Frame Shift Del (DEL) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- USP9X | c.5248del p.L1750Ffs*14 | Frame Shift Del (DEL) | VAF 15/38 reads (39%) | called by mutect2, pindel, varscan2
- AC090517.4 | c.909G>A p.K303= | Silent (SNP) | VAF 3/37 reads (8%) | catalogued as COSV99974207; called by muse, mutect2
- AFF2 | c.2100T>A p.P700= | Silent (SNP) | VAF 28/75 reads (37%) | catalogued as COSV99662629; called by muse, mutect2, varscan2
- ARF4 | c.345A>G p.E115= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100327146; called by muse, mutect2, varscan2
- C12orf4 | c.483G>A p.V161= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as rs144033494; called by muse, mutect2, varscan2
- CACNA1C | c.2382G>T p.P794= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV59712954; called by muse, mutect2, varscan2
- CCDC96 | c.747G>A p.L249= | Silent (SNP) | VAF 32/152 reads (21%) | catalogued as COSV100027843; called by muse, mutect2, varscan2
- CLNK | c.612C>T p.S204= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV99904765; called by muse, mutect2, varscan2
- CUBN | c.984T>A p.P328= | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100912279; called by muse, mutect2, varscan2
- DAB1 | c.1215T>C p.V405= (on ENST00000371231; = p.V372= on NM_021080.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 34/129 reads (26%) | catalogued as COSV100976199; called by muse, mutect2, varscan2
- DIAPH1 | c.3378C>T p.P1126= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as rs977061013, COSV99526062; called by muse, mutect2, varscan2
- DMWD | c.1140C>T p.T380= | Silent (SNP) | VAF 28/112 reads (25%) | catalogued as rs746836020, COSV99352872; called by muse, mutect2, varscan2
- DNAH7 | c.7543C>A p.R2515= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV100414372; called by muse, mutect2, varscan2
- DPH7 | c.420G>A p.E140= | Silent (SNP) | VAF 46/224 reads (21%) | catalogued as COSV99483416; called by muse, varscan2
- ECM1 | c.198C>T p.G66= | Silent (SNP) | VAF 28/157 reads (18%) | catalogued as COSV100681776; called by muse, mutect2, varscan2
- F5 | c.4365A>G p.S1455= | Silent (SNP) | VAF 21/67 reads (31%) | catalogued as COSV100888994; called by muse, mutect2, varscan2
- F8 | c.3825T>C p.D1275= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs201930056, COSV100811374; called by muse, mutect2, varscan2
- GOLGA2 | c.1518G>A p.A506= | Silent (SNP) | VAF 130/284 reads (46%) | catalogued as rs146436048; called by muse, mutect2, varscan2
- ITCH | c.2253A>G p.E751= (on ENST00000262650 / NM_001257137.3; = p.E710= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99392150; called by muse, mutect2, varscan2
- JARID2 | c.2223A>T p.T741= | Silent (SNP) | VAF 54/228 reads (24%) | catalogued as COSV100521544; called by muse, mutect2, varscan2
- KIAA0408 | c.840G>A p.S280= | Silent (SNP) | VAF 27/139 reads (19%) | catalogued as rs138966810; called by muse, mutect2, varscan2
- LAMA4 | c.354C>A p.I118= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as COSV100037881; called by muse, mutect2, varscan2
- MERTK | c.2910C>T p.S970= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as COSV54931234; called by muse, mutect2, varscan2
- MRPS2 | c.546C>T p.L182= | Silent (SNP) | VAF 20/53 reads (38%) | catalogued as COSV99613317, COSV99613714; called by muse, mutect2, varscan2
- NCCRP1 | c.598C>T p.L200= | Silent (SNP) | VAF 37/221 reads (17%) | catalogued as COSV100355762; called by muse, mutect2, varscan2
- NRXN2 | c.2904C>A p.I968= | Silent (SNP) | VAF 11/59 reads (19%) | catalogued as rs754016916, COSV99633054; called by muse, mutect2, varscan2
- OR11H6 | c.174A>G p.L58= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100209738; called by muse, mutect2, varscan2
- OR2B3 | c.654T>C p.Y218= | Silent (SNP) | VAF 13/80 reads (16%) | catalogued as rs1344622035, COSV101013759; called by muse, mutect2, varscan2
- OR6A2 | c.906C>A p.V302= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV60265575; called by muse, mutect2, varscan2
- PCDHB9 | c.1692G>A p.P564= | Silent (SNP) | VAF 20/119 reads (17%) | catalogued as rs1554283192; called by muse, mutect2, varscan2
- PHF7 | c.1062G>A p.K354= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs776307386, COSV100015337; called by muse, mutect2, varscan2
- PLA2G6 | c.1794C>T p.L598= | Silent (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100140282; called by muse, mutect2, varscan2
- SDSL | c.639C>T p.A213= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as rs367940348; called by muse, mutect2, varscan2
- SGTA | c.108C>T p.I36= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV99682498; called by muse, mutect2, varscan2
- SLC12A3 | c.825C>T p.S275= | Silent (SNP) | VAF 5/43 reads (12%) | catalogued as rs140167332; called by muse, mutect2, varscan2
- SLC22A15 | c.1227G>A p.L409= | Silent (SNP) | VAF 58/242 reads (24%) | catalogued as COSV101047634; called by muse, mutect2, varscan2
- SLC7A13 | c.78C>T p.I26= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV99878633; called by muse, mutect2, varscan2
- SPATA9 | c.651G>A p.P217= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs779907736, COSV57224192, COSV99174160; called by muse, mutect2, varscan2
- SVEP1 | c.7662C>A p.I2554= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV99928585, COSV99929452; called by muse, mutect2, varscan2
- TMTC4 | c.1830C>A p.A610= (on ENST00000376234 / NM_001350577.2; = p.A629= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV100168536; called by muse, mutect2, varscan2
- TNFRSF25 | c.6G>A p.E2= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs766095125, COSV100556327; called by muse, varscan2
- UNC13D | c.1773G>A p.P591= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs367988204; called by muse, mutect2
- CTBP2 | c.58+11838G>A | Intron (SNP) | VAF 11/79 reads (14%) | catalogued as COSV100456234; called by muse, mutect2, varscan2
- MIR517C | n.59C>G | RNA (SNP) | VAF 10/66 reads (15%) | catalogued as rs940577054; called by muse, mutect2, varscan2
- RTEL1 | c.3652+91G>C | Intron (SNP) | VAF 9/57 reads (16%) | catalogued as COSV99422817, COSV99423025; called by muse, mutect2, varscan2
